Somatic mutation profile of tumor specimen MMRF_1810_1_BM_CD138pos (aliquot MMRF_1810_1_BM_CD138pos_T1_KBS5U_K11325) from MMRF case MMRF_1810, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,473 days).
Specimen MMRF_1810_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe0e96e0-8627-48fd-852f-1950f1715d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1810_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1810_1_PB_Whole_C2_KBS5U_K11326; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e777878e-640f-49f6-8f36-65104a142bcc

The open-access MAF lists 90 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 23, Silent 15, Intron 5, 5'UTR 3, Nonsense Mutation 1, In Frame Del 1, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIPL1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1468979428; called by muse, mutect2, varscan2
- CCDC168 | c.19715C>G p.S6572C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59420810; called by muse, mutect2
- CSMD3 | c.1474C>T p.P492S (on ENST00000297405 / NM_001363185.1; = p.P388S on NM_052900.3) | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759641145; called by muse, mutect2, varscan2
- EPPK1 | c.5276T>C p.I1759T | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1554659703; called by muse, mutect2, varscan2
- FOLR3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs765420568; called by muse, mutect2, varscan2
- FOXN1 | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs762513012, COSV56882628; called by muse, mutect2, varscan2
- HEATR1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100857421; called by muse, mutect2
- LRIG1 | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs767414411, COSV56237373; called by muse, mutect2, varscan2
- MUC5AC | c.14876G>A p.R4959H | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1372136194, COSV64370892; called by muse, mutect2
- NKX2-3 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs988758307, COSV60728493; called by muse, mutect2, varscan2
- RAG1 | c.2894A>T p.E965V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV55024401; called by muse, mutect2
- RPGRIP1 | c.3239-1G>C p.X1080_splice | Splice Site (SNP) | VAF 71/148 reads (48%) | catalogued as rs766360783; called by muse, mutect2, varscan2
- STRIP2 | c.2248G>C p.G750R | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974041; called by muse, mutect2, varscan2
- TTPA | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1418663437; called by muse, mutect2, varscan2
- UNC13C | c.3761G>A p.R1254K | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.306); catalogued as rs1260625146, COSV52933270; called by muse, mutect2
- ZIC4 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67172104; called by muse, mutect2, varscan2
- ZNF536 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62817522; called by muse, mutect2, varscan2
- ABCD2 | c.939G>A p.K313= | Splice Region (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- ADGRF1 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ANGPTL5 | c.800A>G p.E267G | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGEF10 | c.2495T>A p.F832Y (on ENST00000398564; = p.F807Y on NM_014629.4) | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- C1RL | c.596A>T p.Y199F | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CABS1 | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- CAGE1 | c.797C>G p.S266* (on ENST00000512086; = p.S130* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- CCDC168 | c.15814G>A p.E5272K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2
- DNAH12 | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- DOCK10 | c.3922G>T p.D1308Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DOCK8 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- FSIP2 | c.9414A>T p.Q3138H | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.18919T>G p.S6307A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- HSF1 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.3580G>A p.G1194S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2
- IGHV2-70D | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, varscan2
- KCNF1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MAN2A1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTRH2 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TEX47 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 94/150 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TEX51 | c.365C>G p.A122G | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2
- THYN1 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLN1 | c.5209T>G p.Y1737D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, varscan2
- TLN1 | c.5192_5203del p.V1731_M1734del | In Frame Del (DEL) | VAF 28/120 reads (23%) | called by pindel, varscan2
- USP53 | c.902A>G p.H301R | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF732 | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- C2CD3 | c.6126A>T p.V2042= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- CORIN | c.2106G>T p.L702= | Silent (SNP) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- DNER | c.1314G>T p.P438= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV59170109; called by muse, mutect2, varscan2
- FAM178B | c.1239C>T p.D413= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs1357321249, COSV59970515; called by muse, mutect2, varscan2
- FARP1 | c.1305G>T p.A435= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV60337674; called by muse, mutect2, varscan2
- GRM6 | c.2322C>T p.G774= | Silent (SNP) | VAF 73/224 reads (33%) | catalogued as rs763674392, COSV51436365; called by muse, mutect2, varscan2
- IGHV1-24 | c.67C>T p.L23= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs111257793; called by muse, mutect2, varscan2
- IGHV2-70D | c.120C>T p.T40= | Silent (SNP) | VAF 19/20 reads (95%) | called by muse, varscan2
- KIF1A | c.873A>G p.G291= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs770972213; called by mutect2, varscan2
- MAP1B | c.1638G>A p.K546= | Silent (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- MORC1 | c.2898T>A p.T966= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- PTPN5 | c.879G>A p.K293= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- RELCH | c.3297A>G p.L1099= | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as rs1334239116; called by muse, mutect2, varscan2
- SLC23A1 | c.963C>T p.V321= | Silent (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.1116C>T p.A372= | Silent (SNP) | VAF 52/189 reads (28%) | catalogued as rs1426292764; called by muse, mutect2, varscan2
- ARHGEF7 | c.1789-119C>G | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- ATXN3 | c.*2331G>T | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- BACH2 | c.*4385C>A | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- CCDC116 | c.*254C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CSPG5 | c.-762C>T | 5'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- FER | c.*5119C>T | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- FRG1CP | n.988G>A | RNA (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- GANC | c.*173A>G | 3'UTR (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- GLB1L2 | c.804+42C>T | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs374456329; called by muse, varscan2
- GPATCH2 | c.*880A>T | 3'UTR (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- HMGN4 | c.*514C>T | 3'UTR (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- HS1BP3 | c.920+1046G>A | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as rs1397573768; called by muse, mutect2
- IL1RL1 | c.970+1512C>A | Intron (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- IL1RN | c.-23C>A | 5'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- KL | c.*1316A>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- MMP16 | c.*5663G>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as rs1306492546; called by muse, mutect2
- NFXL1 | c.*771C>G | 3'UTR (SNP) | VAF 12/97 reads (12%) | catalogued as rs1159653006; called by muse, mutect2, varscan2
- NGFR | c.*572del | 3'UTR (DEL) | VAF 44/104 reads (42%) | catalogued as rs1169016861; called by mutect2, pindel, varscan2
- NR2F2 | c.*223T>C | 3'UTR (SNP) | VAF 12/130 reads (9%) | catalogued as rs771382116; called by muse, mutect2
- PABPC5 | c.*1433C>G | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- POGLUT3 | c.*2149A>T | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- PTBP3 | c.8+472G>A | Intron (SNP) | VAF 22/72 reads (31%) | called by mutect2, varscan2
- PURB | c.*4582T>C | 3'UTR (SNP) | VAF 70/108 reads (65%) | called by muse, mutect2, varscan2
- RPE65 | c.*598A>C | 3'UTR (SNP) | VAF 46/103 reads (45%) | catalogued as COSV52019119; called by muse, mutect2, varscan2
- SLC2A3 | c.*522T>C | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- SLCO1A2 | c.*2625C>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- SNTN | c.*1414A>G | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*2579dup | 3'UTR (INS) | VAF 37/68 reads (54%) | catalogued as rs1364176857; called by mutect2, varscan2
- STIMATE | c.*2488_*2507del | 3'UTR (DEL) | VAF 6/86 reads (7%) | catalogued as COSV104422124; called by mutect2, varscan2
- TOR1AIP2 | c.-59A>T | 5'UTR (SNP) | VAF 132/548 reads (24%) | called by muse, varscan2
- TRIM4 | c.*623G>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.*197_*199del | 3'UTR (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
